Surgical pathology report (de-identified scan), TCGA case TCGA-UB-A7MC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-A7MC-01A (Primary Tumor).

[page 1 of 6]
Results

Surgical Pathology

(enter 1 per line): Specimen #1 LEFT HEPATIC
ARTERY LYMPH NODE for perm

Result Information

Status (Last updated Date/Time)

Accession #

Result Impression

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Sex: Male

Soc. Sec. #:

Accession #:

Visit #:

Service

Receive

Locatio

Client:

Physici

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Carcinoma, hepatocellular
pleomorphic
8175/3
Site: Liver C22.0
9/26/13

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph node, left hepatic artery, biopsy: No tumor in one lymph node (0/1).
- B. Lymph node, cystic artery, biopsy: No tumor in one lymph node (0/1).
- C. Gallbladder, cholecystectomy: Focal mucosal autolysis, otherwise no significant pathologic abnormality.
- D. Lymph node, portal caval, biopsy: No tumor in one lymph node (0/1).
- E. Liver, right lobe, partial hepatectomy:
1. Hepatocellular carcinoma, two foci, 9 cm and 7 cm in greatest dimension, moderately to poorly differentiated with vascular invasion, margins negative; see comment.
2. Chronic hepatitis B (activity grade 1, fibrosis stage 2); see comment.

COMMENT:

Liver Tumor, Including Intrahepatic Bile Duct, Synoptic Comment

- Tumor type: Hepatocellular carcinoma: mixed type with trabecular,

[page 2 of 6]
[REDACTED]

pleomorphic, and pseudoglandular areas.

- Histologic grade: Moderately to poorly differentiated.
- Tumor size (maximum diameter of largest lesion): 9 cm.
- Tumor necrosis: <10%.
- Multifocality (more than one tumor separated by nontumorous liver parenchyma): Present.
- Estimated total tumor diameter of all HCC foci: 16 cm.
- Vascular invasion: Present in small vessels (slide E5).
- Hepatic capsule: Tumor abuts capsule.
- Local extension of tumor: Confined to liver.
- Hepatic surgical margins: Negative; tumor is 0.9 cm from the surgical resection margin.
- The tumor is within 4 mm of the diaphragm and within 0.5 mm of the site marked IVC sidewall.
- Non-neoplastic liver: Hepatitis B.
- Iron stain: Negative (performed and evaluated on block E10).
- Hepatocellular nodules (in cirrhotic liver): None.
- Lymph node status: Negative; total number of nodes examined: 3.
- AJCC Stage: pT3aN0.

To further characterize the background liver, immunohistochemical stains for hepatitis B virus surface and core antigens were obtained on sections of non-neoplastic liver (block E10). Hepatocytes showed diffuse staining for HBV surface antigen and were negative for core antigen, supporting a diagnosis of chronic Hepatitis B.

Trichome stain was performed on block E10 and highlights the presence of septal fibrosis with occasional bridging fibrosis without architectural distortion, consistent with an overall fibrosis stage 2.

Immunostain for vascular marker (ERG) was performed and evaluated on block E5 and confirms the diagnosis of vascular invasion.

has reviewed slides E5 and E7 (H&E and ERG stains) and agrees with the diagnosis of vascular invasion.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Specimen(s) Received
A:left hepatic artery lymph node
B:cystic artery lymph node
C:gallbladder
D:portal caval lymph node
E:right hepatectomy with partial diaphragm

Clinical History

Collection Time:

[REDACTED]

[page 3 of 6]
[REDACTED]

Relevant History: yo w/hx of HBV (recently started Tenofovir) who complained of right groin pain. Workup included a CT scan that demonstrated a large liver mass. The case was discussed at liver tumor board with recommendations to pursue surgical resection.

The patient is a year-old man with a history of hepatitis B virus (recently started Tenofovir) and heavy alcohol use. CT scan on showed a large liver mass. He is now undergoing resection. According to imaging found a bilobed, heterogeneously enhancing mass centered in segment 7 of the liver. The mass is partially exophytic and has contact with the right hemidiaphragm. There is mass effect on the IVC and on the right hepatic vein.

Gross Description

The case is received in five parts, labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "left hepatic artery LN," and consists of a single intact, ovoid lymph node (1.1 x 0.6 x 0.5 cm). The node is bisected to reveal a grossly unremarkable, solid, tan-pink cut surface. The nodes is submitted in its entirety in cassette A1.

Part B is received fresh and additionally labeled "cystic artery LN," and consists of a single tan-brown, ovoid, intact lymph node (1.1 x 0.6 x 0.3 cm) with scant attached soft, yellow fibroadipose tissue. The node is bivalved to reveal a grossly unremarkable, solid, tan-pink cut surface. The node is submitted in its entirety in cassette B1.

Part C is received fresh and additionally labeled "gallbladder," and consists of an intact gallbladder (5.5 cm in length, 2.1 cm in diameter at fundus, 1.1 cm diameter a neck). The gallbladder is bright-green and has a smooth and glistening serosal surface. The adventitial surface is dull and ragged but intact. The cystic duct margin measures 0.5 cm in outside diameter and is free of impacting calculi. The gallbladder contains thin, green bile and is devoid of stones. The gallbladder wall is thin and pliable, of even thickness (0.2 cm) and free of any areas of induration. The gallbladder mucosa is green and velvety, free of any areas of ulceration or polyps. No cystic duct lymph node is identified. Representative sections, including the inked cystic duct margin, are submitted in cassette C1.

Part D is received fresh and additionally labeled "portal caval LN," and consists of a single intact, ovoid lymph node (1.6 x 0.8 x 0.7 cm) with a scant amount of attached yellow, lobulated adipose tissue. The node is sectioned to reveal a congested but otherwise grossly unremarkable, tan-pink cut surface. The node is submitted in its entirety in cassette D1.

Part E is received fresh and additionally labeled "right hepatectomy with partial diaphragm," and consists of a portion of liver (885 gm; 13.5 cm from right to left x 11 cm from anterior to posterior x 18 cm from superior to inferior). There is an exophytic mass on the superior surface, which has been cut in to prior to receipt by Pathology, and harvested for banking by . The mass is soft, yellow-gold and homogenous (7 x 6 x 6 cm), and is within 0.1 cm of the capsule and 0.7 cm from the surgical resection margin. There is a second lesion adjacent to the first lesion, which is larger and appears to be a distinct lesion, and is soft, yellow-gold and focally hemorrhagic (9 x 6

[REDACTED]

[page 4 of 6]
[REDACTED]

x 6 cm) and is 1.4 cm from the surgical resection margin. There is a vessel running between the two lesions, which does not appear to be involved. There is an oval white-tan fragment of diaphragm on the superior surface of the specimen. The tumor appears to be abutting, but does not invade the diaphragm. The remainder of the hepatic parenchyma is firm, red-brown and without nodules.

ORIENTED BY : Surgeon's sutures (black short stitch = sidewall of vena cava, black long stitch = right hepatic vein).

INKING:

- Surgical margin: Black.
- Right hepatic vein: Yellow.
- Sidewall vena cava: Green.
- Diaphragm: Green.

CASSETTES: Representative sections are submitted as follows:

- E1: Right hepatic vein margin.
- E2: Vessel between lesions.
- E3: Lesion #1, closest approach to capsule.
- E4: Lesion #1, closest approach to diaphragm.
- E5: Lesion #1, with adjacent normal parenchyma.
- E6: Lesion #2.
- E7: Lesion #2, with adjacent normal.
- E8: Lesion #2, closest approach to capsule.
- E9: Lesion #1.
- E10: Uninvolved hepatic parenchyma.
- E11: Lesion #1 with IVC sidewall.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on

Pathology PDF Report

Show images for Surgical Pathology
ARTERY LYMPH NODE for perm

(enter 1 per line): Specimen #1 LEFT HEPATIC

Authorizing Provider Information

Name:

Phone:

Signed by

Signed

Phone

Pager

Result History

SURGICAL PATHOLOGY

Surgical Pathology
NODE for perm

(enter 1 per line): Specimen #1 LEFT HEPATIC ARTERY LYMPH

This is NOT a Requisition. Requisition hyperlink below.

[REDACTED]

[page 5 of 6]
Surgical Pathology**(enter 1 per line): Specimen #1 LEFT****HEPATIC ARTERY LYMPH NODE for perm** Authorizin**Pathology and Cytology**

Departmei

Show images for Surgical Pathology
ARTERY LYMPH NODE for perm

(enter 1 per line): Specimen #1 LEFT HEPATIC

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order DetailsFrequency
OnceDuration
1 occurrencePriority
RoutineOrder Class
Unit Collect**Order Questions**

Question

Answer

Comment

Specimen (enter 1 per line)

Specimen #1
LEFT HEPATIC
ARTERY LYMPH
NODE for perm
yo w/hx of HBV
(recently started
Tenofovir) who
complained of
right groin pain.
Workup included a
CT scan that
demonstrated a
large liver mass.
The case was
discussed a
liver tumor board
with
recommnedations
to pursue surgical
resection.

Lab Collection and Receipt Information

Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

Collection Information

Resulting Agency

[page 6 of 6]
Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User			--
Authorizing Provider			--
Billing Provider			--

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

Acknowledgement Info

For	At	Acknowledged By	Acknowledged On
-----	----	-----------------	-----------------

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order Requisition

Surgical Pathology

(enter 1 per line): Specimen #1 LEFT HEPATIC ARTERY LYMPH

NODE for pern

Primary, Tumor Site Discrepancy		☒
HPV/AA Discrepancy		☒

Source: NCI Genomic Data Commons file 86e8ce57-425e-46cd-b862-4690fb763682 (TCGA-UB-A7MC.B391B6EA-425D-411D-AA4C-EE43B861E807.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).